TCGA case TCGA-FF-8047 — Lymphoid Neoplasm Diffuse Large B-cell Lymphoma (TCGA-DLBC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mature B-Cell Lymphomas; Primary site: Lymph nodes; Tissue source site: SingHealth. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f978cb0f-d319-4c01-b4c5-23ae1403a106

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: Singapore; Age at index: 38 years; Vital status: Alive.

Diagnoses (2)
1. Diffuse large B-cell lymphoma, NOS (the primary disease): ICD-O-3 morphology code: 9680/3; ICD-10 code: C83.3; Tissue or organ of origin: Lymph nodes of head, face and neck; Site of resection or biopsy: Lymph nodes of head, face and neck; Classification of tumor: primary; Age at diagnosis: 38.3 years (13,996 days); Year of diagnosis: 2011; AJCC staging edition: 7th; Ann Arbor clinical stage: Stage II; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 126 days; Ann Arbor extranodal involvement: No; Max tumor bulk site: Cervical lymph nodes; Sites of involvement: Lymph Node, Cervical / Lymph Node, Inguinal.
   Pathology details: Additional pathology findings: Percent follicular component <= 10%.
   Pathology details: Bone marrow malignant cells: No; Consistent pathology review: Yes; Greatest tumor dimension: 2 cm; Measurement unit: Centimeters.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Etoposide + Ifosfamide + Ofatumumab; Initial disease status: Initial Diagnosis; Regimen or line of therapy: O-ICE; Days to treatment start: 19 days; Days to treatment end: 59 days; Number of cycles: 2; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Dexamethasone + Doxorubicin + Vincristine; Initial disease status: Progressive Disease; Regimen or line of therapy: HyperCVAD; Days to treatment start: 59 days; Days to treatment end: 80 days; Number of cycles: 1; Clinical trial indicator: Yes.
   Recorded as not given: adjuvant Radiation Therapy, NOS; Stem Cell Transplantation, NOS.
2. Progression of diagnosis 1 (Diffuse large B-cell lymphoma, NOS), site: Meninges, NOS. Age at diagnosis: 38.4 years (14,020 days); Days to diagnosis: 24 days; Prior treatment: Yes.

Follow-up (4 entries)
- Day 24 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Meninges, NOS; Days to progression: 24 days.
- Days to follow up: 126 days; Disease response: With Tumor.
- ECOG performance status: 2.
- Imaging type: PET; Imaging result: Positive; Timepoint: Within 2 Months After Completion of First-Course Treatment.

Molecular and laboratory tests
- BCL2 (FISH): Normal.
- BCL2 (IHC): Positive.
- BCL6 (IHC): Positive.
- BCL6 translocation (FISH): Positive.
- CCND1 (FISH): Normal.
- CCND1 (IHC): Negative.
- CD10 (IHC): Negative.
- CD20 (IHC): Positive.
- IGH translocation (FISH): Positive.
- IRF4 (IHC): Positive.
- MALT1 (FISH): Normal.
- MYC translocation (FISH): Positive.
- PAX5 (FISH): Normal.
- Lactate Dehydrogenase 667 IU [Blood test normal range upper: 380].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 52.5 kg; Height: 155 cm; BMI: 21.9.
- Timepoint category: Prior to Diagnosis; Risk factors: Hepatitis B Infection.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-FF-8047-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
  Slide TCGA-FF-8047-01A-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-FF-8047-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-FF-8047-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-FF-8047-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Diffuse large B-cell lymphoma (DLBCL) NOS (any anatomic site nodal or extranodal); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: With tumor.
- Stage record, Ann arbor: B symptoms present indicator: No.
- History of disease: History relevant infectious diagnosis: Hepatitis B Virus.
- Primary pathology: Follicular component percent: < or = 10%; Tumor resected max dimension: 2.0; Maximum tumor bulk anatomic site: Cervical.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: cervical; Lymph node involvement site: Inguinal.
- Tests performed: LDH level: 667; Mib 1 positive percent range: 76 - 100%.
- Tests performed, Genetic testing results, Genetic testing result 1: Immunopheotypic analysis tested: CD10 > 30%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunopheotypic analysis tested: BCL2; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunopheotypic analysis tested: CD20; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunopheotypic analysis tested: MUM1 > 30%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunopheotypic analysis tested: BCL6 > 30%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunopheotypic analysis tested: Cyclin D1; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 1: Genetic abnormality tested: C-myc; Genetic abnormality tested other: PAX5.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 2: Genetic abnormality tested: BCL2; Genetic abnormality tested other: IGH.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 3: Genetic abnormality tested: BCL6.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 4: Genetic abnormality tested: CCND1.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 5: Genetic abnormality tested: MALT1.
- Drug treatment 1: Stem cell transplantation: No; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify).
- Drug treatment 2: Pharmaceutical therapy drug name: ICE; Stem cell transplantation: No; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify).
- Drug treatment 4: Pharmaceutical therapy drug name: Cvad; Stem cell transplantation: No; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify).

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 126 days; disease-specific survival: no event (censored), 126 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 24 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-FF-8047-01A-11D-2209-01): tumor purity 0.93, ploidy 1.94, whole-genome doublings 0.
